Surgical pathology report (de-identified scan), TCGA case TCGA-RY-A83Y, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of California San Francisco, specimen TCGA-RY-A83Y-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED] Visit #: [REDACTED]
DOB: [REDACTED] (Age:) Sex: Male
Soc. Sec. #: [REDACTED] Location:
Physician(s): [REDACTED]

Accession #: [REDACTED]
Service Date: [REDACTED]
Received: [REDACTED]
Client: [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

- A. Brain, left parietal lobe, biopsy: Oligodendroglioma, WHO grade II; see comment.
B. Brain, left parietal, excision: Oligodendroglioma, WHO grade II; see comment.
C. Brain, Cavitron ultrasonic surgical aspiration: Oligodendroglioma, WHO grade II; see comment.

Oligodendroglioma, grade II 9450/3
Site: Brain, supratentorial NOS C71.0
COMMENT: *path @ Brain, parietal lobe C71.3 4/10/30/13*

This oligodendroglioma shows typical features, with a moderately cellular proliferation of neoplastic oligodendroglia showing uniform round nuclei. The mitotic activity is low, with up to 1 mitotic figure/10 HPFs. No necrosis or microvascular proliferation is seen.

A macrophage infiltrate is intermixed with the tumor, and multiple vessels are cuffed by macrophages.

Immunohistochemistry for IDH1 and MIB-1 will be performed on block A2 and the results will be reported in an addendum. In addition, fluorescence in-situ hybridization for 1p19q will be performed on block A2 at the [REDACTED] and the results will be reported separately.

[REDACTED] has reviewed select slides of the case and agrees with the diagnosis.

Intraoperative Diagnosis

FS1 (A) Brain, biopsy: Infiltrating glioma, favor oligodendroglioma, at least WHO grade II. Tissue section and cytologic preparation.

Gross Description

The specimen is received fresh in three parts, each labeled with the patient's name and medical record number.

Part A, additionally labeled "L tumor - FS + perm," consists of multiple, irregular, friable, tan to pink

[page 2 of 2]
glistening tissue fragments (1.2 x 0.8 x 0.3 cm). A representative section is frozen for frozen section diagnosis 1 and a touch prep is created. The entire specimen is submitted in cassettes as follows:

A1: Frozen section 1 remnant.
A2: Remaining tissue.

Part B, additionally labeled "tumor," consists of one pink, irregular, unoriented soft tissue fragment (1 x 1 x 0.3 cm). The specimen is submitted intact in cassette B1.

Part C, additionally labeled "CUSA contents," consists of multiple soft, pink, irregular, unoriented soft tissue fragments (5 x 5 x 2 cm in aggregate). Representative sections are submitted in cassettes C1-C8. All of the remaining tissue is submitted in cassettes C9-C16.

Clinical History

The patient is a -year-old man who presented with seizures, and a left parietal mass with a small area of focal ring enhancement, on Decadron and Keppra. Per MRI shows an ill-defined, cortically based T2/FLAIR hyperintense mass involving the left postcentral gyrus and left inferior parietal lobule.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

Pathology Resident

Signed: /Pathologist

Addendum

Date Ordered:
Date Complete:
Date Reported:

Status: Signed Out
By:

Addendum Comment

Immunohistochemical studies performed and evaluated at show that the neoplastic cells are **positive** with the antibodies against IDH-1 (R132H mutant) protein (on A2).

MIB1 labeling on A2 is estimated at approximately 4%.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the . They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

Pathologist

Electronically signed out on

Source: NCI Genomic Data Commons file 178c7db7-c46e-4035-8032-81ae8a3e1295 (TCGA-RY-A83Y.EEC58176-5007-4A8F-9BBB-ABE5B1D13772.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).